Somatic mutation profile of tumor specimen TCGA-E8-A44K-01A (aliquot TCGA-E8-A44K-01A-21D-A23U-08) from TCGA case TCGA-E8-A44K, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 50.6 years (18,472 days).
Specimen TCGA-E8-A44K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0fca9cd-e261-406a-ac8e-cd5ccb7ec4ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A44K-10A (Blood Derived Normal), aliquot TCGA-E8-A44K-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed0814fc-3fdb-4f9e-8194-01d51f3aeaa4

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BNC2 | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV66147428, COSV66149984; called by muse, mutect2, varscan2
- DISP1 | c.1624T>G p.S542A | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.329); catalogued as COSV52660741; called by muse, mutect2, varscan2
- GNPAT | c.1867T>A p.L623I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64153661, COSV64153911; called by muse, mutect2
- SLC44A2 | c.1337A>T p.Q446L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100213104; called by muse, mutect2, varscan2
- TRIOBP | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.203); catalogued as COSV60379559; called by muse, mutect2, varscan2
- ELL2 | c.15del p.T6Qfs*27 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel
- ADCK2 | c.1810C>T p.L604= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV50781919, COSV50782645; called by muse, mutect2, varscan2
- HSF5 | c.828A>G p.V276= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as COSV60417498; called by muse, mutect2, varscan2
- RIF1 | c.576G>A p.V192= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99690293; called by muse, mutect2
- RTN2 | c.228G>C p.G76= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV55594699; called by muse, mutect2, varscan2
- ZNF580 | c.21G>A p.R7= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs760701650, COSV54401257; called by mutect2, varscan2
